Somatic mutation profile of tumor specimen TCGA-G7-A4TM-01A (aliquot TCGA-G7-A4TM-01A-11D-A31X-10) from TCGA case TCGA-G7-A4TM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 41.0 years (14,966 days).
Specimen TCGA-G7-A4TM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfb91ae1-995c-4f5d-bfc0-efd04acc65b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-A4TM-10B (Blood Derived Normal), aliquot TCGA-G7-A4TM-10B-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ea75496-7d51-4dd6-9ad7-05f06871c7c4

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 20, Silent 11, Frame Shift Del 3, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC1 | c.2308G>A p.G770R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60687475; called by muse, mutect2, varscan2
- ACER1 | c.571C>A p.R191S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56835760, COSV56837054; called by muse, mutect2, varscan2
- ARHGEF28 | c.4730A>T p.N1577I | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV55258826; called by muse, mutect2, varscan2
- CAPN12 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1195357557, COSV53146912; called by muse, mutect2, varscan2
- CENPF | c.3938A>T p.E1313V | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV65275636; called by muse, mutect2, varscan2
- CIC | c.2839C>T p.P947S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV50589304; called by muse, mutect2, varscan2
- COG4 | c.511T>A p.S171T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as COSV60423264; called by muse, mutect2, varscan2
- DSP | c.6661G>C p.E2221Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV101131153, COSV65793318; called by muse, mutect2, varscan2
- ELL3 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55856699; called by muse, mutect2, varscan2
- FOXJ3 | c.346A>T p.R116* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as COSV62362861; called by muse, mutect2, varscan2
- HOXB4 | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60178537; called by muse, mutect2, varscan2
- KIAA0100 | c.6097C>G p.R2033G | Missense Mutation (SNP) | VAF 80/130 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56382428, COSV99972380; called by muse, mutect2, varscan2
- NCAM2 | c.924A>C p.K308N | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.485); catalogued as COSV53080445; called by muse, mutect2, varscan2
- NOG | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 99/170 reads (58%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.828); catalogued as COSV60447185; called by muse, varscan2
- PEAK1 | c.3205G>T p.D1069Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV56937297; called by muse, mutect2, varscan2
- PRUNE2 | c.8155C>T p.H2719Y | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.335); catalogued as COSV100944515, COSV65048875; called by mutect2, varscan2
- SINHCAF | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 230/406 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61797330; called by muse, mutect2, varscan2
- SLC3A1 | c.1399A>G p.M467V | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as rs1216343981, COSV53223147; called by muse, mutect2, varscan2
- TMEM94 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV58596638; called by muse, mutect2, varscan2
- TNRC6A | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV59365283; called by muse, mutect2, varscan2
- WAPL | c.2315T>C p.I772T | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750612471, COSV53936131; called by muse, mutect2, varscan2
- AHDC1 | c.1954_1955del p.T652Pfs*41 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by pindel, varscan2
- COQ9 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- KMT2C | c.8380_8386del p.P2794Kfs*27 | Frame Shift Del (DEL) | VAF 34/95 reads (36%) | called by mutect2, pindel, varscan2
- PAQR7 | c.576_578del p.N192del | In Frame Del (DEL) | VAF 42/99 reads (42%) | called by mutect2, pindel, varscan2
- ZNF529 | c.619del p.T207Pfs*4 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- AHNAK | c.474G>A p.T158= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs1369834876, COSV57216400; called by muse, mutect2, varscan2
- ARFGEF2 | c.1308C>G p.L436= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV64210105; called by muse, mutect2, varscan2
- CLTA | c.519C>T p.F173= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs764210568, COSV54254810; called by muse, mutect2, varscan2
- CREBBP | c.942C>T p.I314= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV52126798; called by muse, mutect2
- DCBLD2 | c.216T>C p.C72= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as COSV58790282; called by muse, mutect2, varscan2
- EXOSC9 | c.36C>T p.R12= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as COSV54666397; called by muse, mutect2, varscan2
- KCTD10 | c.892C>A p.R298= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as rs1174156681, COSV57326787, COSV57327142; called by muse, mutect2
- MAML1 | c.2226G>A p.V742= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV52986171, COSV52988917; called by muse, mutect2, varscan2
- PIWIL4 | c.1896C>T p.D632= | Silent (SNP) | VAF 60/150 reads (40%) | catalogued as rs770380977, COSV54409864; called by muse, mutect2, varscan2
- RHOC | c.435G>C p.R145= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as COSV53518052; called by muse, mutect2, varscan2
- RNF139 | c.159C>T p.L53= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV57834999; called by muse, mutect2, varscan2
